Gene-level copy-number profile of tumor specimen TCGA-B6-A0RH-01A from TCGA case TCGA-B6-A0RH, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 51.4 years (18,759 days).
Specimen TCGA-B6-A0RH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.5994c06d-ee9b-4ead-b3d1-2e1f286f7d6d.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-B6-A0RH-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 816 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/fb8135e3-d7be-466f-a862-d34026bf387b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 4; copy number 1: 9,303; copy number 2: 43,110; copy number 3: 3,337; copy number 4: 3,364; copy number 5: 558; copy number 6: 96; copy number 8: 12; copy number 13: 23.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-B6-A0RH-01A-21D-A111-01): tumor purity 0.66, ploidy 2.02, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr16:69,762,328–69,964,452, 4 genes (within-gene range 0–1): WWP2, SNORA62, MIR140, CLEC18A.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 689 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:165,772,904–193,277,738, 456 genes, copy number 5–8 (broad region; genes not listed).
- chr3:195,260,632–196,736,007, 70 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr17:38,195,703–38,405,593, 4 genes, copy number 6: NPEPPSP1, MRPL45, GPR179, SOCS7.
- chr17:38,450,394–38,452,444, 1 gene, copy number 6: AC244153.1.
- chr17:39,200,283–41,786,931, 158 genes, copy number 5–13 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 9,303. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
